Surgical pathology report (de-identified scan), TCGA case TCGA-55-1592, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-1592-01A (Primary Tumor).

☒ TEST: Surgical Pathology

Result Name	Results	Units	Reference Range
☒ Surgical Pathology	COPY TO:		

COPY TO:

Frozen Section Diagnosis: Large cell carcinoma, margins free

Performed by

Pre-Op Diagnosis

Left lung cancer

Post-Op Diagnosis

Same as above

Clinical History

Same as above

Gross Description:

Received in a single container labeled wedge resection left upper lobe. The specimen consists of a wedge resection of the lung measuring 9 x 6 x 1.5 cm. The pleural surface is yellow to red tan and slightly anthracotic. On sectioning reveals a circumscribed white tan firm nodule measuring 2 cm in greatest dimension that is 0.1 cm from the pleural surface and extends 1 cm from the resection margin. A representative section was examined at the time of surgery. Received with the specimen are cassettes labeled Representative sections are submitted as follows: A frozen section, B shaved resection margin, C through F additional sections from nodule.

Microscopic Description:

The slides labeled are examined. See diagnosis.

Final Diagnosis

Lung, left upper lobe (wedge biopsy):

Adenocarcinoma:

- moderately differentiated
- measuring 2.0 cm in greatest diameter
- extending up to but not through pleura
- tumor identified within endothelial lined lymphovascular space
- areas of fibrosis
- lymph nodes: No lymph nodes resected (see comment) PAS 9

SPC-A

CPT: 88307, 88331

Comments

The frozen section diagnosis is confirmed.

In some areas dense fibrosis is present associated with the tumor. Although the adenocarcinoma grows along alveolar spaces, the areas of fibrosis remove this from the differential diagnosis of a bronchoalveolar carcinoma. The tumor focally extends up to the pleural surface but does not extend into the pleural surface. This test has been finalized at the Campus.

Source: NCI Genomic Data Commons file 2b9b9171-883c-4173-9efe-1049d64e235e (TCGA-55-1592.99AE36EE-BB6C-4934-8E5C-388FF5A69C46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).